CCDI case PBCDPB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/619cc491-81e7-46aa-b140-84677cf3bb8c

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 14.6 years (5,340 days).

Biospecimens (3 samples)
- Sample 0DPHSY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPHTC, 0DPHTP (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
